Somatic mutation profile of tumor specimen ALCH-B2RQ-TTP1-A (aliquot ALCH-B2RQ-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2RQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 55.7 years (20,347 days).
Specimen ALCH-B2RQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98ac89be-65d5-4810-afc2-67b077fad569.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2RQ-NB1-A (Blood Derived Normal), aliquot ALCH-B2RQ-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b22bffa-d84a-4f2c-9192-b7a679785318

The open-access MAF lists 290 somatic variants for this specimen: 208 protein-altering or splice-affecting, 47 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 178, Silent 47, Intron 21, Nonsense Mutation 13, Frame Shift Del 12, RNA 9, Splice Site 4, 3'UTR 4, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.2513C>A p.S838* | Nonsense Mutation (SNP) | VAF 60/212 reads (28%) | catalogued as rs1131690908, CM952423, COSV57298758, COSV57309724; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 145/442 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM2 | c.10G>T p.V4F | Missense Mutation (SNP) | VAF 161/513 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV55864232; called by muse, mutect2, varscan2
- ADCY7 | c.1016C>T p.S339L | Missense Mutation (SNP) | VAF 72/420 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1037736769; called by muse, mutect2, varscan2
- AKAP9 | c.5604C>A p.D1868E (on ENST00000359028; = p.D1836E on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/453 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV62357442; called by muse, mutect2, varscan2
- AMPD1 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 97/406 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1235554869; called by muse, mutect2, varscan2
- ATG4C | c.962del p.G321Vfs*21 | Frame Shift Del (DEL) | VAF 44/266 reads (17%) | catalogued as rs759118785; called by mutect2, pindel, varscan2
- ATP8B4 | c.1082G>T p.R361L | Missense Mutation (SNP) | VAF 97/438 reads (22%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.491); catalogued as COSV52711717; called by muse, mutect2, varscan2
- BST1 | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 46/534 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs777458820; called by muse, mutect2
- CARD10 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 171/658 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV52657104; called by muse, mutect2, varscan2
- CDH10 | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 80/511 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52589358; called by muse, mutect2, varscan2
- CFAP46 | c.151C>G p.L51V | Missense Mutation (SNP) | VAF 71/187 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.578); catalogued as COSV100886501; called by muse, mutect2, varscan2
- CFAP61 | c.2464G>T p.A822S | Missense Mutation (SNP) | VAF 55/206 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV55621147; called by muse, mutect2, varscan2
- COG7 | c.1147G>T p.E383* | Nonsense Mutation (SNP) | VAF 123/595 reads (21%) | catalogued as rs1204231695; called by muse, mutect2, varscan2
- CSMD3 | c.5836C>T p.R1946C (on ENST00000297405 / NM_001363185.1; = p.R1842C on NM_052900.3) | Missense Mutation (SNP) | VAF 115/522 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs377290204; called by muse, mutect2, varscan2
- DISP3 | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 103/360 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1404234836, COSV53826028; called by muse, mutect2, varscan2
- ECT2 | c.862A>G p.N288D (on ENST00000392692 / NM_001349098.2; = p.N257D on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/200 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1319228548; called by muse, mutect2, varscan2
- EML6 | c.628A>G p.I210V | Missense Mutation (SNP) | VAF 76/428 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1335080852; called by muse, varscan2
- EP300 | c.2744G>A p.R915H | Missense Mutation (SNP) | VAF 48/598 reads (8%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.045); catalogued as rs748820220, COSV99608101; ClinVar: benign; called by muse, mutect2
- ERP44 | c.527G>C p.R176T | Missense Mutation (SNP) | VAF 38/256 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.038); catalogued as rs1176275130; called by muse, mutect2, varscan2
- EXOC4 | c.2320T>C p.C774R | Missense Mutation (SNP) | VAF 73/342 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764386579; called by muse, mutect2, varscan2
- EYS | c.516G>T p.Q172H | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.017); catalogued as COSV100675678; called by muse, mutect2, varscan2
- FOXD4L1 | c.703C>G p.L235V | Missense Mutation (SNP) | VAF 103/346 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); catalogued as COSV99380899; called by muse, mutect2, varscan2
- FUT10 | c.819G>C p.Q273H | Missense Mutation (SNP) | VAF 47/242 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs771351372, COSV59452713; called by muse, mutect2, varscan2
- GABRP | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 209/460 reads (45%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.967); catalogued as rs149935911; called by muse, mutect2, varscan2
- GIPC1 | c.149del p.P50Lfs*48 | Frame Shift Del (DEL) | VAF 40/150 reads (27%) | catalogued as rs771881138; called by mutect2, varscan2
- GPM6A | c.567G>T p.K189N | Missense Mutation (SNP) | VAF 31/386 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.129); catalogued as rs765394151; called by muse, mutect2
- HCN1 | c.2353C>A p.P785T | Missense Mutation (SNP) | VAF 149/740 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.058); catalogued as COSV57511193; called by muse, mutect2, varscan2
- HERC6 | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as rs966304676; called by muse, mutect2, varscan2
- HERC6 | c.1019C>G p.A340G | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.297); catalogued as COSV52031298; called by muse, mutect2, varscan2
- HOXA5 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 56/227 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as rs776801900, COSV56075132; called by muse, mutect2, varscan2
- HS3ST4 | c.392G>A p.G131D | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.085); catalogued as COSV58800491; called by muse, mutect2, varscan2
- KDM5C | c.3223G>C p.V1075L | Missense Mutation (SNP) | VAF 107/241 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.439); catalogued as CD153267; called by muse, mutect2, varscan2
- KIF7 | c.3011G>T p.R1004L | Missense Mutation (SNP) | VAF 93/410 reads (23%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.995); catalogued as COSV51539545; called by muse, mutect2, varscan2
- KLHL35 | c.723C>A p.H241Q | Missense Mutation (SNP) | VAF 177/558 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.481); catalogued as rs778877895; called by muse, mutect2, varscan2
- LAMA4 | c.919G>T p.A307S (on ENST00000230538 / NM_001105206.3; = p.A300S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/1104 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.325); catalogued as COSV57893745, COSV57906568; called by muse, varscan2
- LTB4R | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 65/221 reads (29%) | SIFT tolerated (0.79); PolyPhen benign (0.061); catalogued as rs1478353966; called by muse, mutect2, varscan2
- MAGEE1 | c.2500G>T p.G834C | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63910708; called by muse, mutect2, varscan2
- NAPEPLD | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1227054803, COSV100440063; called by muse, mutect2, varscan2
- NRXN2 | c.136G>A p.G46S | Missense Mutation (SNP) | VAF 53/264 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs768737747; called by muse, mutect2, varscan2
- NXF1 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs772236957, COSV53677147; called by muse, mutect2, varscan2
- OR2AK2 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1447192220, COSV100824349; called by muse, mutect2, varscan2
- OR4A5 | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 42/271 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as rs1310473677, COSV100157042, COSV60525244; called by muse, mutect2, varscan2
- OR51B6 | c.917C>A p.S306Y | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.786); catalogued as COSV100970500; called by mutect2, varscan2
- OR6P1 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 428/1352 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs752851619, COSV58109539; called by muse, mutect2, varscan2
- P2RX7 | c.1012G>A p.G338S | Missense Mutation (SNP) | VAF 62/345 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55856631; called by muse, mutect2, varscan2
- PCDHA1 | c.2215C>G p.L739V | Missense Mutation (SNP) | VAF 84/204 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.057); catalogued as COSV65373329; called by muse, mutect2, varscan2
- PCLO | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 139/564 reads (25%) | catalogued as COSV61612629; called by muse, mutect2, varscan2
- PCSK5 | c.4744A>G p.T1582A | Missense Mutation (SNP) | VAF 132/941 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs1045419141; called by muse, mutect2, varscan2
- PHIP | c.4427C>G p.S1476C | Missense Mutation (SNP) | VAF 60/356 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV51503331; called by muse, mutect2, varscan2
- PKP1 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 204/578 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.241); catalogued as rs761063340; called by muse, mutect2, varscan2
- PLCH1 | c.3893C>T p.A1298V (on ENST00000340059 / NM_001130960.2; = p.A1290V on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/346 reads (22%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs376193266; called by muse, mutect2, varscan2
- PLEKHG4 | c.1103G>T p.G368V | Missense Mutation (SNP) | VAF 169/726 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1208095447; called by muse, mutect2, varscan2
- PMVK | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 113/360 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.208); catalogued as rs370067596; called by muse, mutect2, varscan2
- PODXL | c.1193G>A p.R398Q (on ENST00000378555 / NM_001018111.3; = p.R366Q on NM_005397.4) | Missense Mutation (SNP) | VAF 30/473 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.023); catalogued as rs201911803; called by muse, mutect2
- PRB2 | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 38/324 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as COSV66982246; called by muse, varscan2
- PSIP1 | c.1213C>T p.R405* | Nonsense Mutation (SNP) | VAF 40/99 reads (40%) | catalogued as COSV66255220; called by muse, mutect2, varscan2
- PXDNL | c.4087C>A p.Q1363K | Missense Mutation (SNP) | VAF 70/239 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV62488360; called by muse, mutect2, varscan2
- SATB2 | c.1327C>T p.P443S | Missense Mutation (SNP) | VAF 208/654 reads (32%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.146); catalogued as COSV99613076; called by muse, mutect2, varscan2
- SLITRK3 | c.1318G>T p.G440W | Missense Mutation (SNP) | VAF 119/768 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99578218; called by muse, mutect2, varscan2
- SMARCD3 | c.892G>C p.D298H (on ENST00000262188 / NM_001003801.2; = p.D285H on NM_003078.4) | Missense Mutation (SNP) | VAF 128/613 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99223444; called by muse, mutect2, varscan2
- SPAG5 | c.695T>C p.L232S | Missense Mutation (SNP) | VAF 97/443 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.085); catalogued as COSV58800529; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 92/624 reads (15%) | catalogued as COSV59572566; called by muse, mutect2, varscan2
- THSD7A | c.3560G>A p.R1187Q | Missense Mutation (SNP) | VAF 30/317 reads (9%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.692); catalogued as rs770506365; called by muse, mutect2
- TLCD3B | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1473585587; called by muse, mutect2
- TLE1 | c.1252A>G p.M418V | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs749393803; called by muse, mutect2, varscan2
- TRPA1 | c.1798A>G p.I600V | Missense Mutation (SNP) | VAF 175/549 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as rs1236229851; called by muse, mutect2, varscan2
- TTN | c.53272del p.R17758Efs*37 (on ENST00000591111; = p.R10334Efs*37 on NM_003319.4) | Frame Shift Del (DEL) | VAF 100/589 reads (17%) | catalogued as COSV100635497; called by mutect2, pindel, varscan2
- TYR | c.1211A>T p.H404L | Missense Mutation (SNP) | VAF 101/398 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as CM981982; called by muse, mutect2, varscan2
- UNC13C | c.3856G>T p.V1286L | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as COSV52856929; called by muse, mutect2, varscan2
- UNC79 | c.6412A>G p.K2138E (on ENST00000393151 / NM_001346218.2; = p.K1961E on NM_020818.5) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV99830156; called by muse, varscan2
- WDR41 | c.1121G>T p.R374I | Missense Mutation (SNP) | VAF 72/182 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as COSV57001165; called by muse, mutect2, varscan2
- ABCC9 | c.2702C>T p.T901I | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAM19 | c.1722G>T p.K574N | Missense Mutation (SNP) | VAF 107/253 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAP2 | c.112T>A p.Y38N | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ADGRA2 | c.2284G>C p.V762L | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADGRL4 | c.282T>A p.S94R | Missense Mutation (SNP) | VAF 57/201 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- AFF4 | c.728T>C p.M243T | Missense Mutation (SNP) | VAF 218/614 reads (36%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- AL441992.2 | c.1149G>C p.E383D | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALMS1 | c.6536C>T p.T2179I | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- ANKH | c.1396G>C p.E466Q | Missense Mutation (SNP) | VAF 163/664 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ANKRD13C | c.1173G>C p.E391D | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.131); called by muse, mutect2
- ARFGEF1 | c.164A>T p.H55L | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0); called by mutect2, varscan2
- ARHGAP18 | c.210G>T p.L70F | Missense Mutation (SNP) | VAF 93/366 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- ASTN2 | c.439C>A p.L147M | Missense Mutation (SNP) | VAF 92/475 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ATAD2B | c.652C>T p.R218* | Nonsense Mutation (SNP) | VAF 38/199 reads (19%) | called by muse, mutect2, varscan2
- BMT2 | c.490G>T p.G164* | Nonsense Mutation (SNP) | VAF 48/195 reads (25%) | called by muse, mutect2, varscan2
- BOLA1 | c.344G>C p.R115T | Missense Mutation (SNP) | VAF 43/370 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BRINP3 | c.2021A>T p.H674L | Missense Mutation (SNP) | VAF 94/323 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- BTBD2 | c.408G>A p.R136= | Splice Region (SNP) | VAF 70/239 reads (29%) | called by muse, mutect2, varscan2
- BYSL | c.1253G>T p.R418M | Missense Mutation (SNP) | VAF 59/183 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C1QL2 | c.361C>A p.L121M | Missense Mutation (SNP) | VAF 102/317 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- C1orf216 | c.394G>T p.G132W | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CA2 | c.755A>T p.N252I | Missense Mutation (SNP) | VAF 145/474 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- CACNA1I | c.6509T>G p.L2170R | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAPN2 | c.637G>C p.E213Q | Missense Mutation (SNP) | VAF 41/323 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CBLN4 | c.418A>T p.M140L | Missense Mutation (SNP) | VAF 82/288 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- CBLN4 | c.417G>C p.L139F | Missense Mutation (SNP) | VAF 80/284 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CCDC127 | c.351G>C p.K117N | Missense Mutation (SNP) | VAF 103/557 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- CCDC39 | c.181A>C p.N61H | Missense Mutation (SNP) | VAF 25/510 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CCNG2 | c.728A>C p.Y243S | Missense Mutation (SNP) | VAF 63/249 reads (25%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- CDH4 | c.571G>T p.V191L | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CDK20 | c.76-2A>T p.X26_splice | Splice Site (SNP) | VAF 132/556 reads (24%) | called by muse, mutect2, varscan2
- CDT1 | c.403G>T p.A135S | Missense Mutation (SNP) | VAF 155/614 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CEP295NL | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 130/742 reads (18%) | called by muse, mutect2, varscan2
- CFAP221 | c.2158T>A p.W720R | Missense Mutation (SNP) | VAF 119/377 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHORDC1 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- CLUL1 | c.925G>C p.D309H | Missense Mutation (SNP) | VAF 30/236 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.273); called by muse, mutect2
- COG7 | c.1148A>T p.E383V | Missense Mutation (SNP) | VAF 125/607 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- COL11A1 | c.71T>A p.L24* | Nonsense Mutation (SNP) | VAF 165/701 reads (24%) | called by muse, mutect2, varscan2
- COL22A1 | c.3089C>T p.P1030L | Missense Mutation (SNP) | VAF 104/479 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL22A1 | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 133/525 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSMD3 | c.10531A>G p.K3511E (on ENST00000297405 / NM_001363185.1; = p.K3342E on NM_052900.3) | Missense Mutation (SNP) | VAF 118/511 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- DBR1 | c.74G>T p.R25L | Missense Mutation (SNP) | VAF 350/716 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- DMD | c.7466T>C p.L2489P | Missense Mutation (SNP) | VAF 114/228 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DPP6 | c.936A>T p.R312S (on ENST00000377770 / NM_001364500.2; = p.R250S on NM_001936.5) | Missense Mutation (SNP) | VAF 80/392 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSCAM | c.1135G>T p.D379Y | Missense Mutation (SNP) | VAF 129/426 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- DYNC1H1 | c.12578G>T p.R4193L | Missense Mutation (SNP) | VAF 234/850 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DYNC2H1 | c.9682G>T p.E3228* | Nonsense Mutation (SNP) | VAF 76/307 reads (25%) | called by muse, mutect2, varscan2
- EPB41L2 | c.1358G>T p.S453I | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPS15 | c.1853del p.D618Vfs*68 | Frame Shift Del (DEL) | VAF 39/201 reads (19%) | called by mutect2, pindel, varscan2
- EXOC4 | c.2321G>T p.C774F | Missense Mutation (SNP) | VAF 69/332 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EXPH5 | c.63C>G p.I21M | Missense Mutation (SNP) | VAF 31/444 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); called by muse, mutect2
- FAM135B | c.1004T>A p.L335H | Missense Mutation (SNP) | VAF 86/329 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT4 | c.4872del p.D1625Mfs*11 | Frame Shift Del (DEL) | VAF 54/321 reads (17%) | called by mutect2, pindel, varscan2
- FGL1 | c.83del p.Q28Rfs*95 | Frame Shift Del (DEL) | VAF 58/220 reads (26%) | called by mutect2, pindel, varscan2
- FHOD1 | c.28G>T p.G10* | Nonsense Mutation (SNP) | VAF 67/295 reads (23%) | called by muse, mutect2, varscan2
- FRMD3 | c.1677A>T p.L559F | Missense Mutation (SNP) | VAF 147/831 reads (18%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FSTL3 | c.767C>A p.A256E | Missense Mutation (SNP) | VAF 81/403 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLE1 | c.1093G>T p.A365S | Missense Mutation (SNP) | VAF 132/673 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.146); called by muse, varscan2
- GNMT | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 40/214 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- HELQ | c.1360A>T p.I454F | Missense Mutation (SNP) | VAF 54/213 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- HERC2 | c.4851C>A p.H1617Q | Missense Mutation (SNP) | VAF 49/349 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- HOXD12 | c.454del p.L152Cfs*21 | Frame Shift Del (DEL) | VAF 94/325 reads (29%) | called by mutect2, pindel, varscan2
- HOXD4 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 71/558 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- HRG | c.1171C>A p.P391T | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.053); called by muse, mutect2
- IGF2R | c.4224C>A p.C1408* | Nonsense Mutation (SNP) | VAF 57/343 reads (17%) | called by muse, mutect2, varscan2
- IGHD | c.100C>T p.H34Y | Missense Mutation (SNP) | VAF 212/827 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- INPP5J | c.2159A>C p.D720A (on ENST00000331075 / NM_001284285.2; = p.D352A on NM_001002837.2) | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITK | c.437A>T p.Y146F | Missense Mutation (SNP) | VAF 126/333 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRT6A | c.8G>A p.S3N | Missense Mutation (SNP) | VAF 385/1613 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KRTAP9-1 | c.103A>G p.T35A | Missense Mutation (SNP) | VAF 210/807 reads (26%) | SIFT tolerated (0.19); called by muse, mutect2, varscan2
- LHCGR | c.1714G>C p.A572P | Missense Mutation (SNP) | VAF 141/706 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LHX1 | c.1100C>A p.S367Y | Missense Mutation (SNP) | VAF 70/261 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- LRRC7 | c.2005G>C p.V669L (on ENST00000651989 / NM_001370785.2; = p.V636L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- MALRD1 | c.6410C>G p.S2137* | Nonsense Mutation (SNP) | VAF 68/225 reads (30%) | called by muse, mutect2, varscan2
- MAP3K11 | c.830C>T p.T277I | Missense Mutation (SNP) | VAF 44/661 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- MAT2A | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 79/262 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- MEX3C | c.1436G>T p.W479L | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- MGAM2 | c.1511T>A p.L504H | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- NALCN | c.3904A>T p.M1302L | Missense Mutation (SNP) | VAF 56/183 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.055); called by muse, varscan2
- NEFL | c.1310G>T p.R437L | Missense Mutation (SNP) | VAF 212/698 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- NME8 | c.853C>A p.Q285K | Missense Mutation (SNP) | VAF 69/328 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- NOM1 | c.1328A>T p.E443V | Missense Mutation (SNP) | VAF 145/596 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- NSD3 | c.509C>G p.S170C | Missense Mutation (SNP) | VAF 117/401 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OPRM1 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 49/202 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4C5 | c.976G>C p.D326H | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- OR51B4 | c.45C>G p.F15L | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR7A17 | c.184T>C p.F62L | Missense Mutation (SNP) | VAF 38/281 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.714); called by muse, mutect2
- OTUD4 | c.1900C>G p.H634D (on ENST00000447906 / NM_001366057.1; = p.H569D on NM_001102653.1) | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- OTUD7B | c.364G>C p.G122R | Missense Mutation (SNP) | VAF 122/350 reads (35%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- PAX1 | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 48/367 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDH11Y | c.2672C>A p.P891Q (on ENST00000400457 / NM_032973.2; = p.P880Q on NM_032971.3) | Missense Mutation (SNP) | VAF 222/420 reads (53%) | SIFT tolerated (0.85); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- PLCL1 | c.2996-1G>T p.X999_splice | Splice Site (SNP) | VAF 16/88 reads (18%) | called by muse, varscan2
- PLCL1 | c.3260A>T p.E1087V | Missense Mutation (SNP) | VAF 28/241 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- PMFBP1 | c.476T>G p.L159W | Missense Mutation (SNP) | VAF 157/674 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- PTGER2 | c.311C>A p.P104H | Missense Mutation (SNP) | VAF 67/439 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- PTPN3 | c.307del p.L103Cfs*5 | Frame Shift Del (DEL) | VAF 89/290 reads (31%) | called by mutect2, pindel, varscan2
- PTPRQ | c.6372G>C p.W2124C (on ENST00000616559; = p.W2091C on NM_001145026.2) | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PYGB | c.1820G>A p.G607E | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RIMS1 | c.4351del p.Q1451Sfs*12 | Frame Shift Del (DEL) | VAF 44/183 reads (24%) | called by pindel, varscan2
- RPL8 | c.82C>A p.R28S | Missense Mutation (SNP) | VAF 25/225 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- SCAF1 | c.2144C>T p.P715L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SCN7A | c.1768G>T p.A590S | Missense Mutation (SNP) | VAF 43/288 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SLF2 | c.2291C>G p.S764C | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLIT3 | c.2224G>C p.G742R | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SNX13 | c.2137A>G p.S713G | Missense Mutation (SNP) | VAF 45/245 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SOCS4 | c.743A>G p.K248R | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPAG17 | c.6611C>T p.T2204I | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- STOX1 | c.2218G>C p.D740H | Missense Mutation (SNP) | VAF 49/427 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- STX3 | c.786+1G>A p.X262_splice | Splice Site (SNP) | VAF 38/159 reads (24%) | called by muse, mutect2, varscan2
- SURF6 | c.1014G>T p.E338D | Missense Mutation (SNP) | VAF 59/264 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- SYNE3 | c.169G>T p.G57W | Missense Mutation (SNP) | VAF 52/230 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAS2R14 | c.274A>G p.I92V | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TERB1 | c.357A>C p.K119N | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, varscan2
- THOP1 | c.1293G>T p.Q431H | Missense Mutation (SNP) | VAF 81/298 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TNKS | c.3482G>T p.R1161L | Missense Mutation (SNP) | VAF 91/291 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TNR | c.2123A>T p.K708M | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); called by muse, mutect2
- TPH1 | c.104T>A p.L35Q | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TPRG1 | c.238G>C p.D80H | Missense Mutation (SNP) | VAF 58/391 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAPPC9 | c.1543C>T p.P515S | Missense Mutation (SNP) | VAF 270/976 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TRBV3-1 | c.274C>T p.H92Y | Missense Mutation (SNP) | VAF 64/238 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.825); called by muse, varscan2
- TRIR | c.161del p.G54Afs*3 | Frame Shift Del (DEL) | VAF 127/592 reads (21%) | called by mutect2, pindel, varscan2
- TRPM5 | c.906+1del p.X302_splice | Splice Site (DEL) | VAF 10/45 reads (22%) | called by mutect2, pindel, varscan2
- TTN | c.16564C>T p.P5522S (on ENST00000591111; = p.P4595S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/168 reads (35%) | PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- TUBB8B | c.100G>T p.G34C | Missense Mutation (SNP) | VAF 66/552 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, varscan2
- UNC13C | c.5239A>C p.I1747L | Missense Mutation (SNP) | VAF 52/293 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- USH2A | c.6230C>A p.P2077Q | Missense Mutation (SNP) | VAF 51/338 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- USP17L7 | c.702G>T p.K234N | Missense Mutation (SNP) | VAF 166/2046 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.013); called by muse, mutect2
- VPS13C | c.7057C>A p.L2353I (on ENST00000644861 / NM_020821.3; = p.L2310I on NM_017684.5) | Missense Mutation (SNP) | VAF 64/265 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- WASHC5 | c.301A>G p.S101G | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ZNF208 | c.3503C>A p.P1168H | Missense Mutation (SNP) | VAF 52/317 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF23 | c.438del p.K147Nfs*10 | Frame Shift Del (DEL) | VAF 37/260 reads (14%) | called by mutect2, pindel, varscan2
- ZNF345 | c.470T>C p.F157S | Missense Mutation (SNP) | VAF 61/319 reads (19%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ZNF680 | c.815del p.G272Afs*15 | Frame Shift Del (DEL) | VAF 23/150 reads (15%) | called by mutect2, pindel, varscan2
- ZNF737 | c.871G>T p.G291C | Missense Mutation (SNP) | VAF 79/464 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- ZNRF2 | c.119G>C p.G40A | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.794); called by muse, mutect2
- ZXDC | c.2201G>T p.G734V | Missense Mutation (SNP) | VAF 110/491 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- ABCA2 | c.1455C>T p.T485= (on ENST00000614293; = p.T455= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 180/420 reads (43%) | called by muse, mutect2, varscan2
- ACAA2 | c.30T>A p.V10= | Silent (SNP) | VAF 28/100 reads (28%) | called by muse, mutect2, varscan2
- AL121899.2 | c.1230G>T p.A410= | Silent (SNP) | VAF 218/759 reads (29%) | catalogued as COSV67352036; called by muse, mutect2, varscan2
- C22orf39 | c.282C>T p.D94= | Silent (SNP) | VAF 58/253 reads (23%) | called by muse, mutect2, varscan2
- CYP4F2 | c.1380C>T p.P460= | Silent (SNP) | VAF 56/216 reads (26%) | called by muse, mutect2, varscan2
- DNAH1 | c.1881C>T p.S627= | Silent (SNP) | VAF 25/306 reads (8%) | catalogued as rs193290403; ClinVar: likely benign; called by muse, mutect2
- DPY19L2 | c.1797A>T p.I599= | Silent (SNP) | VAF 31/215 reads (14%) | called by muse, mutect2, varscan2
- ELK4 | c.456C>G p.L152= | Silent (SNP) | VAF 43/282 reads (15%) | called by muse, mutect2, varscan2
- EML6 | c.3534C>T p.V1178= | Silent (SNP) | VAF 67/171 reads (39%) | called by muse, mutect2, varscan2
- H4C12 | c.81C>T p.I27= | Silent (SNP) | VAF 42/266 reads (16%) | catalogued as rs540518456; called by muse, mutect2, varscan2
- HHIP | c.1698A>G p.S566= | Silent (SNP) | VAF 35/171 reads (20%) | called by muse, mutect2, varscan2
- HHLA1 | c.240G>T p.L80= | Silent (SNP) | VAF 90/466 reads (19%) | called by muse, mutect2, varscan2
- HOXA10 | c.456G>C p.P152= | Silent (SNP) | VAF 248/928 reads (27%) | catalogued as COSV52230606; called by muse, mutect2, varscan2
- KCNG4 | c.975G>T p.G325= | Silent (SNP) | VAF 53/157 reads (34%) | catalogued as rs113623603, COSV57583892; called by muse, mutect2, varscan2
- KLB | c.909T>C p.H303= | Silent (SNP) | VAF 52/137 reads (38%) | called by muse, mutect2, varscan2
- KLHL2 | c.165G>A p.L55= | Silent (SNP) | VAF 42/242 reads (17%) | catalogued as rs772024619, COSV56984073; called by muse, mutect2, varscan2
- MCCC1 | c.1425C>G p.G475= | Silent (SNP) | VAF 445/1116 reads (40%) | catalogued as rs750286197; called by muse, mutect2, varscan2
- MFSD12 | c.540C>A p.T180= | Silent (SNP) | VAF 136/521 reads (26%) | called by muse, mutect2, varscan2
- MGAT4A | c.687A>G p.K229= | Silent (SNP) | VAF 101/350 reads (29%) | called by muse, mutect2, varscan2
- NR1H4 | c.1065G>A p.P355= (on ENST00000551379 / NM_001206993.2; = p.P341= on NM_005123.4) | Silent (SNP) | VAF 83/384 reads (22%) | catalogued as rs569479207, COSV51857715; called by muse, mutect2, varscan2
- OR2T4 | c.888C>T p.S296= | Silent (SNP) | VAF 186/760 reads (24%) | catalogued as rs1442877835; called by muse, mutect2, varscan2
- PHF21B | c.1281A>G p.E427= | Silent (SNP) | VAF 99/369 reads (27%) | catalogued as rs760520466; called by muse, mutect2, varscan2
- PLA2G4E | c.966T>C p.S322= | Silent (SNP) | VAF 25/166 reads (15%) | called by muse, mutect2, varscan2
- PRG4 | c.1071G>A p.E357= | Silent (SNP) | VAF 122/970 reads (13%) | catalogued as rs780381057; called by muse, varscan2
- PTPRB | c.5358C>T p.F1786= | Silent (SNP) | VAF 70/335 reads (21%) | catalogued as COSV99719741; called by muse, mutect2, varscan2
- RBFA | c.135C>G p.L45= | Silent (SNP) | VAF 189/825 reads (23%) | called by muse, mutect2, varscan2
- REX1BD | c.105C>T p.D35= | Silent (SNP) | VAF 63/231 reads (27%) | called by muse, mutect2, varscan2
- RIBC2 | c.1110G>A p.T370= | Silent (SNP) | VAF 20/215 reads (9%) | catalogued as rs529724786, COSV100734239; called by muse, mutect2
- RYR2 | c.13305C>T p.T4435= | Silent (SNP) | VAF 23/168 reads (14%) | catalogued as COSV63684187; called by muse, mutect2, varscan2
- SALL3 | c.1065G>T p.A355= | Silent (SNP) | VAF 47/206 reads (23%) | called by muse, mutect2, varscan2
- SART1 | c.1983G>A p.V661= | Silent (SNP) | VAF 57/458 reads (12%) | called by muse, mutect2, varscan2
- SCRT2 | c.156C>G p.P52= | Silent (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- SELP | c.2421C>T p.C807= | Silent (SNP) | VAF 30/197 reads (15%) | catalogued as rs1357696394; called by muse, mutect2, varscan2
- STYXL1 | c.837C>T p.C279= | Silent (SNP) | VAF 63/250 reads (25%) | called by muse, mutect2, varscan2
- SYNE2 | c.18258C>T p.I6086= | Silent (SNP) | VAF 130/883 reads (15%) | called by muse, mutect2, varscan2
- TDRD9 | c.159G>T p.A53= | Silent (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- TIPARP | c.954C>T p.N318= | Silent (SNP) | VAF 100/432 reads (23%) | catalogued as rs746139475; called by muse, mutect2, varscan2
- TUBB8B | c.99T>G p.A33= | Silent (SNP) | VAF 67/550 reads (12%) | called by muse, varscan2
- URI1 | c.252C>G p.A84= | Silent (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- VAV1 | c.1833A>T p.G611= | Silent (SNP) | VAF 68/304 reads (22%) | called by muse, mutect2, varscan2
- WDR75 | c.2424G>A p.L808= | Silent (SNP) | VAF 43/291 reads (15%) | called by muse, mutect2, varscan2
- ZAN | c.2193C>T p.S731= | Silent (SNP) | VAF 45/202 reads (22%) | catalogued as COSV61811913; called by muse, mutect2, varscan2
- ZEB2 | c.1401G>T p.V467= | Silent (SNP) | VAF 19/97 reads (20%) | called by muse, mutect2, varscan2
- ZNF208 | c.3504C>A p.P1168= | Silent (SNP) | VAF 55/321 reads (17%) | catalogued as COSV68112241; called by muse, mutect2, varscan2
- ZNF554 | c.1170C>T p.N390= | Silent (SNP) | VAF 72/270 reads (27%) | called by muse, mutect2, varscan2
- ZNF644 | c.555G>A p.K185= | Silent (SNP) | VAF 34/252 reads (13%) | called by muse, mutect2, varscan2
- ZNF891 | c.1080C>G p.S360= | Silent (SNP) | VAF 26/182 reads (14%) | called by muse, mutect2, varscan2
- ADAM6 | n.635G>T | RNA (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
- AL772337.1 | n.858-167G>A | Intron (SNP) | VAF 64/421 reads (15%) | called by muse, mutect2, varscan2
- ASH1L | c.5828+4337C>G | Intron (SNP) | VAF 121/1076 reads (11%) | called by muse, mutect2, varscan2
- BOD1P2 | n.352C>T | RNA (SNP) | VAF 40/280 reads (14%) | called by muse, mutect2, varscan2
- BX119917.1 | n.177C>A | RNA (SNP) | VAF 21/106 reads (20%) | called by muse, mutect2, varscan2
- DCHS2 | n.1490A>T | RNA (SNP) | VAF 112/451 reads (25%) | called by muse, mutect2, varscan2
- DIP2C | c.85+39184G>A | Intron (SNP) | VAF 68/278 reads (24%) | catalogued as rs1423171160; called by muse, mutect2, varscan2
- EFHD1 | c.302+4445C>G | Intron (SNP) | VAF 66/203 reads (33%) | called by muse, mutect2, varscan2
- FAM9C | c.214+94T>C | Intron (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2, varscan2
- FLNA | c.*6_*8del | 3'UTR (DEL) | VAF 15/30 reads (50%) | called by mutect2, pindel, varscan2
- FOLH1B | n.2093C>T | RNA (SNP) | VAF 30/180 reads (17%) | called by muse, mutect2, varscan2
- GAP43 | c.31-12221G>T | Intron (SNP) | VAF 56/175 reads (32%) | called by muse, mutect2, varscan2
- HLA-B | c.1045+25G>C | Intron (SNP) | VAF 121/404 reads (30%) | called by muse, mutect2, varscan2
- LRP4 | c.2093-32G>T | Intron (SNP) | VAF 109/801 reads (14%) | called by muse, mutect2, varscan2
- MALRD1 | c.4688-137T>G | Intron (SNP) | VAF 9/153 reads (6%) | called by muse, mutect2
- MARCHF1 | c.-322-86011C>G | Intron (SNP) | VAF 119/553 reads (22%) | called by muse, mutect2, varscan2
- MED12L | c.1969-858C>T | Intron (SNP) | VAF 28/504 reads (6%) | called by muse, mutect2
- NAPSB | n.762C>A | RNA (SNP) | VAF 127/563 reads (23%) | catalogued as rs1275051490; called by muse, mutect2, varscan2
- NLRP12 | c.*40A>C | 3'UTR (SNP) | VAF 68/475 reads (14%) | called by muse, mutect2, varscan2
- NPHS2 | c.873+51T>A | Intron (SNP) | VAF 40/366 reads (11%) | called by muse, mutect2, varscan2
- OSCAR | c.*345G>A | 3'UTR (SNP) | VAF 68/297 reads (23%) | catalogued as COSV99500033; called by muse, mutect2, varscan2
- PDLIM3 | c.162-1826A>G | Intron (SNP) | VAF 64/331 reads (19%) | called by muse, mutect2, varscan2
- PDZD3 | c.-520G>A | 5'UTR (SNP) | VAF 28/336 reads (8%) | called by muse, mutect2
- PDZRN3 | c.919-3785G>A | Intron (SNP) | VAF 97/399 reads (24%) | called by muse, mutect2, varscan2
- PIP5K1C | c.1920+1450T>A | Intron (SNP) | VAF 69/340 reads (20%) | called by muse, mutect2, varscan2
- PTGER3 | c.*24-16413C>A | Intron (SNP) | VAF 47/244 reads (19%) | called by muse, mutect2, varscan2
- RAB18 | c.*4070G>T | 3'UTR (SNP) | VAF 85/259 reads (33%) | called by muse, mutect2, varscan2
- SATB2 | c.-60+1946C>G | Intron (SNP) | VAF 28/116 reads (24%) | called by muse, mutect2, varscan2
- SINHCAF | c.-21+819G>C | Intron (SNP) | VAF 159/632 reads (25%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-15104C>T | Intron (SNP) | VAF 52/393 reads (13%) | catalogued as COSV101042680; called by muse, varscan2
- SUGCT | c.1089+2675C>T | Intron (SNP) | VAF 76/581 reads (13%) | catalogued as rs778980265, COSV59340250; called by muse, mutect2, varscan2
- TUBB4AP1 | n.478C>G | RNA (SNP) | VAF 89/211 reads (42%) | catalogued as rs1417096078; called by muse, mutect2, varscan2
- TUBBP5 | n.1065T>G | RNA (SNP) | VAF 42/932 reads (5%) | called by muse, mutect2
- TUBBP5 | n.1066G>T | RNA (SNP) | VAF 41/936 reads (4%) | called by muse, mutect2
- USP46 | c.36+870C>G | Intron (SNP) | VAF 170/661 reads (26%) | catalogued as rs981159392; called by muse, mutect2, varscan2
